Somatic mutation profile of tumor specimen 0DLA1U from CCDI case PBBYBW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,174 days).
Specimen 0DLA1U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc78f1a-375c-409f-94e6-81b4f85b3afc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA0W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec47e081-9563-489a-8cd0-2dba8fa4feba

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC2 | c.8284C>G p.R2762G | Missense Mutation (SNP) | VAF 187/1171 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs543946257, COSV55321586; called by muse, mutect2, varscan2
- SETD2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 242/729 reads (33%) | catalogued as COSV57443300; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 84/1571 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/425 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 86/1856 reads (5%) | called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 72/710 reads (10%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 44/363 reads (12%) | called by muse, varscan2
